Somatic mutation profile of tumor specimen MP2PRT-PANDVD-TMP1-A (aliquot MP2PRT-PANDVD-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANDVD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,396 days).
Specimen MP2PRT-PANDVD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24947cbd-2683-4ac1-a5d5-2cfb994a2ea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANDVD-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANDVD-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b605702-cd13-4877-9498-4def35961ba1

The open-access MAF lists 159 somatic variants for this specimen: 118 protein-altering or splice-affecting, 33 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 33, Nonsense Mutation 16, Intron 4, 5'UTR 2, Splice Region 1, 3'UTR 1, Nonstop Mutation 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADL | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748087461; called by muse, mutect2, varscan2
- ADGRL3 | c.1009G>A p.E337K (on ENST00000506720 / NM_001322402.2; = p.E269K on NM_015236.6) | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV72273056; called by muse, mutect2, varscan2
- AP1G2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV58115678; called by muse, mutect2
- ARHGAP44 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 93/1146 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1048621595; called by muse, mutect2
- C12orf54 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs900120333, COSV58361066; called by muse, mutect2, varscan2
- CEACAM18 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV67282955; called by muse, mutect2, varscan2
- CERS5 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs202076776, COSV58189051; called by muse, mutect2
- COL4A1 | c.4811G>C p.C1604S | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101011321; called by muse, mutect2, varscan2
- CUBN | c.6847C>T p.R2283W | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs150117913; ClinVar: uncertain significance; called by muse, mutect2
- DIS3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV58322747, COSV58329738; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 193/396 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2, varscan2
- FADS1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99952276; called by muse, mutect2, varscan2
- FN1 | c.3524C>G p.S1175C | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60564471, COSV60566522; called by muse, mutect2, varscan2
- FRYL | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | catalogued as COSV51955827; called by muse, mutect2
- HS3ST4 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 105/196 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as COSV58810277; called by muse, mutect2, varscan2
- IFNA17 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 185/450 reads (41%) | catalogued as COSV69738157; called by muse, mutect2, varscan2
- KCNQ5 | c.396C>T p.F132= | Splice Region (SNP) | VAF 119/253 reads (47%) | catalogued as COSV59682214; called by muse, mutect2, varscan2
- KMT2A | c.10491G>T p.Q3497H | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV63294754; called by muse, mutect2, varscan2
- LHCGR | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | catalogued as COSV54301941; called by muse, mutect2, varscan2
- MAGEB6B | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs751404306, COSV69689551; called by muse, mutect2, varscan2
- MAP4K4 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 214/466 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.848); catalogued as rs368647388; called by muse, mutect2
- MDM2 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1246173207; called by muse, mutect2
- MID2 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 175/461 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53309836, COSV53312829; called by muse, mutect2, varscan2
- MRPL30 | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV57666876; called by muse, mutect2, varscan2
- MUC17 | c.11521G>A p.D3841N | Missense Mutation (SNP) | VAF 146/557 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100072743; called by muse, mutect2, varscan2
- MYO1C | c.1759G>C p.D587H (on ENST00000648651 / NM_001080779.2; = p.D552H on NM_033375.5) | Missense Mutation (SNP) | VAF 126/611 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs559019503; called by muse, mutect2, varscan2
- OPA3 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV54397990; called by muse, mutect2
- OTUD7B | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 135/403 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); catalogued as rs782581576; called by muse, mutect2, varscan2
- PKP4 | c.2645G>C p.R882T | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100733814; called by muse, mutect2, varscan2
- PLCZ1 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 15/470 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99857116; called by muse, mutect2
- PLOD3 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV56186688; called by muse, varscan2
- PTPRM | c.2272C>T p.L758F | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59842566, COSV59877800; called by muse, mutect2, varscan2
- RNF207 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.155); catalogued as COSV65007702; called by muse, mutect2, varscan2
- RP1L1 | c.5974G>T p.E1992* | Nonsense Mutation (SNP) | VAF 91/458 reads (20%) | catalogued as COSV101223152, COSV66761810; called by muse, mutect2, varscan2
- RTL1 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 105/542 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66016755; called by muse, mutect2, varscan2
- SIGLEC5 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 157/758 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs957047682; called by muse, mutect2, varscan2
- SLC18A2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53690617; called by muse, mutect2, varscan2
- STAR | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs748942681, COSV52417633; called by muse, mutect2, varscan2
- TCHH | c.3931G>C p.D1311H | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs1474971787; called by muse, mutect2, varscan2
- UGGT2 | c.4258C>G p.P1420A | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65078010; called by muse, mutect2
- ZDHHC20 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV100203696; called by muse, mutect2
- ZNF415 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99701855, COSV99702169; called by muse, mutect2, varscan2
- AHCY | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- AHCY | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AL772284.1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- ANKRD18A | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- BIRC6 | c.12685G>C p.D4229H | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC168 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CELSR2 | c.3447C>G p.F1149L | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- CFAP52 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2
- CFAP65 | c.3902C>G p.S1301C | Missense Mutation (SNP) | VAF 108/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFL2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CGB1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 89/678 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CHD5 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 134/407 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- COL4A1 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2
- CTNNA1 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 119/384 reads (31%) | called by muse, mutect2, varscan2
- DAB2IP | c.1755G>C p.W585C (on ENST00000408936; = p.W557C on NM_032552.3) | Missense Mutation (SNP) | VAF 179/364 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX54 | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- DENND4B | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 13/421 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2
- DNAH9 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 149/492 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH9 | c.8707G>A p.G2903R | Missense Mutation (SNP) | VAF 9/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- EBF1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EFCAB5 | c.4069C>G p.L1357V | Missense Mutation (SNP) | VAF 176/522 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFCAB9 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- EML6 | c.4081G>T p.E1361* | Nonsense Mutation (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- ERP27 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- GMDS | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GRIA3 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HKDC1 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2
- IGHV4-59 | c.345_346insTCCTGACGGAGATG p.R116Sfs*2 | Nonsense Mutation (INS) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- IGHV4-61 | c.351_352insTCCTGACGGAGATG p.R118Sfs*2 | Nonsense Mutation (INS) | VAF 42/328 reads (13%) | called by pindel, varscan2
- IGKV5-2 | chr2:88897784 TCT>CCCTCACC | Missense Mutation (INS) | VAF 43/49 reads (88%) | called by pindel, varscan2*
- IGLV4-69 | chr22:22031470 ins CAA | In Frame Ins (INS) | VAF 95/128 reads (74%) | called by pindel, varscan2
- KMT2A | c.8128G>A p.D2710N | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- KMT2A | c.8869G>T p.E2957* | Nonsense Mutation (SNP) | VAF 46/450 reads (10%) | called by muse, mutect2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 130/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMB4 | c.3956C>T p.S1319L | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSM4 | c.419G>C p.*140Sext*42 | Nonstop Mutation (SNP) | VAF 103/493 reads (21%) | called by muse, mutect2, varscan2
- MAP4 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- MGAM2 | c.2451G>C p.K817N | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MUC17 | c.10231G>T p.V3411L | Missense Mutation (SNP) | VAF 166/519 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MUC17 | c.12742G>T p.E4248* | Nonsense Mutation (SNP) | VAF 134/415 reads (32%) | called by muse, mutect2, varscan2
- MYH15 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.4597C>T p.H1533Y | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- NCSTN | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOC4L | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- NOP56 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- OGDH | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 154/373 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2
- OR5M8 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 180/369 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PELP1 | c.185C>G p.S62W | Missense Mutation (SNP) | VAF 132/712 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF2 | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 108/332 reads (33%) | called by muse, mutect2, varscan2
- PIWIL4 | c.2506A>T p.S836C | Missense Mutation (SNP) | VAF 130/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKNOX1 | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 203/294 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCE1 | c.3033G>C p.K1011N | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.367); called by muse, mutect2
- PRIMPOL | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PTPRG | c.3670C>T p.Q1224* | Nonsense Mutation (SNP) | VAF 101/211 reads (48%) | called by muse, mutect2, varscan2
- RETNLB | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RFT1 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RP1L1 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2
- RP1L1 | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- RP1L1 | c.4861G>C p.E1621Q | Missense Mutation (SNP) | VAF 79/460 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SLC26A8 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2
- SNX14 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SOX13 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 140/306 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SPATA31D3 | c.2165C>G p.S722* | Nonsense Mutation (SNP) | VAF 18/24 reads (75%) | called by mutect2, varscan2
- SPHK1 | c.538G>C p.E180Q (on ENST00000392496 / NM_001355139.2; = p.E194Q on NM_021972.4) | Missense Mutation (SNP) | VAF 159/573 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TASOR2 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TASOR2 | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV20 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 26/603 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TRIB1 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 32/532 reads (6%) | called by muse, mutect2
- TRPM3 | c.846C>G p.S282R (on ENST00000357533 / NM_001366142.2; = p.S127R on NM_020952.6) | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TRPM6 | c.5989G>C p.E1997Q | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTC37 | c.3877C>G p.Q1293E | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.10030C>G p.P3344A (on ENST00000591111; = p.P3298A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/373 reads (4%) | PolyPhen benign (0.274); called by muse, mutect2
- VGF | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 213/1000 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF415 | c.1288C>G p.H430D | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF510 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 145/313 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF566 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ARHGEF16 | c.702C>T p.I234= | Silent (SNP) | VAF 161/356 reads (45%) | called by muse, mutect2, varscan2
- ASF1B | c.318C>T p.F106= | Silent (SNP) | VAF 40/638 reads (6%) | called by muse, mutect2
- CCNB3 | c.3066G>A p.G1022= | Silent (SNP) | VAF 72/427 reads (17%) | catalogued as COSV99329534; called by muse, mutect2, varscan2
- CERS5 | c.504C>T p.F168= | Silent (SNP) | VAF 66/209 reads (32%) | called by muse, varscan2
- CSF1R | c.789C>G p.L263= | Silent (SNP) | VAF 185/395 reads (47%) | called by muse, mutect2, varscan2
- DNAH11 | c.4110C>T p.L1370= | Silent (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- FGF6 | c.477C>T p.F159= | Silent (SNP) | VAF 109/238 reads (46%) | catalogued as COSV57404323; called by muse, mutect2, varscan2
- FLG | c.6219A>G p.K2073= | Silent (SNP) | VAF 234/791 reads (30%) | catalogued as rs769415669, CD121395, COSV100910354; called by muse, mutect2
- GCN1 | c.7281C>T p.I2427= | Silent (SNP) | VAF 33/274 reads (12%) | catalogued as rs374646623; called by muse, mutect2, varscan2
- HOXB9 | c.54C>T p.H18= | Silent (SNP) | VAF 96/430 reads (22%) | catalogued as rs535508340; called by muse, mutect2, varscan2
- KBTBD11 | c.897G>A p.A299= | Silent (SNP) | VAF 26/712 reads (4%) | called by muse, mutect2
- KCNC1 | c.672C>A p.I224= | Silent (SNP) | VAF 34/296 reads (11%) | catalogued as rs773018717, COSV56393887; called by muse, mutect2, varscan2
- KIAA0408 | c.1179G>A p.V393= | Silent (SNP) | VAF 118/278 reads (42%) | catalogued as rs751204090; called by muse, mutect2, varscan2
- KLHL1 | c.63C>G p.L21= | Silent (SNP) | VAF 18/694 reads (3%) | catalogued as COSV64769924; called by muse, mutect2
- KRT72 | c.30C>T p.R10= | Silent (SNP) | VAF 14/416 reads (3%) | catalogued as rs1222422528; called by muse, mutect2
- MAP1B | c.7284G>C p.V2428= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- MFHAS1 | c.855C>T p.F285= | Silent (SNP) | VAF 145/410 reads (35%) | catalogued as rs746376157; called by muse, mutect2, varscan2
- MFHAS1 | c.327C>T p.L109= | Silent (SNP) | VAF 179/386 reads (46%) | catalogued as rs1320796836; called by muse, mutect2, varscan2
- MID1 | c.273G>A p.V91= | Silent (SNP) | VAF 228/550 reads (41%) | catalogued as COSV100452327; called by muse, mutect2, varscan2
- MORC2 | c.27G>C p.L9= | Silent (SNP) | VAF 83/353 reads (24%) | called by muse, mutect2, varscan2
- MPI | c.580C>T p.L194= | Silent (SNP) | VAF 117/367 reads (32%) | catalogued as rs1478515729, COSV60396325; called by muse, mutect2, varscan2
- MUC17 | c.13251G>A p.K4417= | Silent (SNP) | VAF 107/319 reads (34%) | called by muse, mutect2, varscan2
- NLRP10 | c.741C>T p.I247= | Silent (SNP) | VAF 170/479 reads (35%) | catalogued as COSV60779629; called by muse, mutect2, varscan2
- PHLPP2 | c.3393C>T p.R1131= | Silent (SNP) | VAF 120/431 reads (28%) | called by muse, mutect2, varscan2
- POM121C | c.1728G>A p.E576= (on ENST00000607367; = p.E334= on NM_001099415.3) | Silent (SNP) | VAF 37/402 reads (9%) | called by muse, mutect2, varscan2
- PRKACA | c.234G>A p.Q78= | Silent (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- PRPF18 | c.630G>A p.V210= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- RDH16 | c.953G>A p.*318= | Silent (SNP) | VAF 85/198 reads (43%) | called by muse, mutect2, varscan2
- RP1L1 | c.4569G>C p.L1523= | Silent (SNP) | VAF 99/428 reads (23%) | called by muse, mutect2, varscan2
- RP1L1 | c.2961G>C p.L987= | Silent (SNP) | VAF 74/423 reads (17%) | catalogued as COSV66756967; called by muse, mutect2, varscan2
- SLITRK3 | c.2613G>A p.L871= | Silent (SNP) | VAF 161/347 reads (46%) | called by muse, mutect2, varscan2
- TCF25 | c.57C>G p.L19= | Silent (SNP) | VAF 190/424 reads (45%) | catalogued as COSV54527978; called by muse, mutect2, varscan2
- VWA3B | c.6G>A p.E2= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as COSV101346022; called by muse, mutect2, varscan2
- CDH4 | c.170-172840G>A | Intron (SNP) | VAF 139/322 reads (43%) | called by muse, mutect2, varscan2
- EMX2 | c.*243C>T | 3'UTR (SNP) | VAF 97/321 reads (30%) | catalogued as rs1480136647; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+8479C>T | Intron (SNP) | VAF 76/225 reads (34%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+12402G>C | Intron (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- LMO2 | c.-153G>A | 5'UTR (SNP) | VAF 271/596 reads (45%) | catalogued as COSV57646826; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-5226C>G | Intron (SNP) | VAF 124/377 reads (33%) | called by muse, mutect2, varscan2
- SEPTIN3 | chr22:41972987 G>C | 5'Flank (SNP) | VAF 59/266 reads (22%) | called by muse, mutect2, varscan2
- TRIB2 | c.-869G>C | 5'UTR (SNP) | VAF 49/428 reads (11%) | called by muse, mutect2, varscan2
